Somatic mutation profile of tumor specimen TCGA-V4-A9E8-01A (aliquot TCGA-V4-A9E8-01A-11D-A39W-08) from TCGA case TCGA-V4-A9E8, project TCGA-UVM (Uveal Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Epithelioid cell melanoma; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 49.5 years (18,073 days).
Specimen TCGA-V4-A9E8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 879e5686-4e4c-4d25-a7c2-f6565176ec5b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V4-A9E8-10A (Blood Derived Normal), aliquot TCGA-V4-A9E8-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4792c0df-6c12-4ee0-bf33-7b22a8ef3d92

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 5, Silent 4, Frame Shift Del 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNA11 | c.626A>T p.Q209L | Missense Mutation (SNP) | VAF 13/39 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1057519742, COSV50017277, COSV50017623, COSV50017882; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MICU1 | c.173A>T p.E58V | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.756); catalogued as rs1338617916; called by muse, mutect2, varscan2
- BAP1 | c.1453_1467delinsAA p.S485Kfs*82 | Frame Shift Del (DEL) | VAF 18/24 reads (75%) | called by pindel, varscan2*
- KDM6A | c.970A>G p.I324V | Missense Mutation (SNP) | VAF 25/32 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- NACA2 | c.52C>T p.Q18* | Nonsense Mutation (SNP) | VAF 20/52 reads (38%) | called by muse, mutect2, varscan2
- PLCB2 | c.522del p.P175Lfs*39 | Frame Shift Del (DEL) | VAF 5/10 reads (50%) | called by mutect2, varscan2
- PSME4 | c.5237C>T p.S1746F | Missense Mutation (SNP) | VAF 54/178 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- RYR2 | c.5166C>A p.N1722K | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.49); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- OR2L3 | c.876G>A p.R292= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as rs772101099, COSV63456267; called by muse, mutect2, varscan2
- PPP1R18 | c.63C>A p.S21= | Silent (SNP) | VAF 77/153 reads (50%) | catalogued as rs965989056; called by muse, mutect2, varscan2
- SLC7A2 | c.1392C>A p.S464= (on ENST00000494857 / NM_001370338.1; = p.S503= on NM_003046.6) | Silent (SNP) | VAF 40/79 reads (51%) | called by muse, mutect2, varscan2
- ZNF354C | c.1401G>A p.P467= | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as rs772333815, COSV59607512; called by muse, mutect2, varscan2
